Gene-level copy-number profile of tumor specimen C3L-00009-01 from CPTAC case C3L-00009, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 76.6 years (27,968 days).
Specimen C3L-00009-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 01e635fd-50ab-4a2a-a5ef-206a78472f3c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00009-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/c472b115-d84b-48d9-b98a-8c5c9b1001f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 217; copy number 1: 7,812; copy number 2: 36,523; copy number 3: 10,579; copy number 4: 3,026; copy number 5: 288; copy number 6: 139; copy number 7: 286; copy number 8: 25; copy number 10: 13.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–2): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr9:60,914,407–62,711,398, 47 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 750 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,229,280–56,388,153, 44 genes, copy number 5 (within-gene range 2–5): PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1.
- chr4:69,721,167–78,544,269, 160 genes, copy number 5–7 (broad region; genes not listed).
- chr12:69,212,108–71,118,247, 39 genes, copy number 7–10: AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr19:27,638,483–28,125,430, 15 genes, copy number 6: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr19:30,850,975–31,349,436, 5 genes, copy number 6 (within-gene range 4–6): AC011507.1, LINC01834, AC020897.1, TSHZ3, LINC01791.
- chr19:31,787,148–33,382,686, 46 genes, copy number 6–10: RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG.
- chr19:50,882,096–51,723,991, 82 genes, copy number 6 (broad region; genes not listed).
- chr19:52,222,225–55,280,381, 262 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:55,376,826–55,407,788, 6 genes, copy number 5: TMEM190, AC020922.3, TMEM238, RPL28, MIR6805, UBE2S.
- chr22:31,292,499–31,338,021, 1 gene, copy number 5 (within-gene range 2–5): PIK3IP1-DT.
- chr22:31,325,804–35,394,214, 90 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,280. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
